Surgical pathology report (de-identified scan), TCGA case TCGA-3R-A8YX, project TCGA-SARC (Sarcoma), tissue source site University of New Mexico, specimen TCGA-3R-A8YX-01A (Primary Tumor).

[page 1 of 2]
Result type: Surgical Pathology Final Report

Result date: [REDACTED]

Result status: Auth (Verified)

Result title: Surgical Procedure

Performed by: [REDACTED]

Verified by: [REDACTED]

Encounter info: [REDACTED]

Contributor system: [REDACTED]

* Final Report *

Surgical Procedure

CASE: [REDACTED]

PATIENT: [REDACTED]

ICD O.3
Liposarcoma, dedifferentiated 8858/3
Site: Retroperitoneum C48.0
Jed 3/11/14

SPECIMENS SUBMITTED:

A. PERITONEAL IMPLANT, RETROPERITONEAL SARCOMA

DIAGNOSIS:

A. RETROPERITONEUM, SUBMITTED AS PERITONEAL IMPLANT:

- HIGH GRADE SARCOMA CONSISTENT WITH HISTORY OF DEDIFFERENTIATED LIPOSARCOMA (SEE COMMENT).

COMMENT: The tumor cells demonstrate spindle morphology with prominent nucleoli and frequent mitoses, consistent with the recent diagnosis of dedifferentiated liposarcoma ([REDACTED]). The lesion extends to the unoriented resection margins. Reviewed by [REDACTED].

CLINICAL INFORMATION: A [REDACTED] with retroperitoneal mass.

GROSS DESCRIPTION: Number of specimen containers: 1. Labeled with patient name [REDACTED] and MRN [REDACTED].

A. Container designation: "peritoneal implant" -- Received unfixed is an irregular portion of yellow to pink/tan firm soft tissue 4 x 3 x 1.2 cm. The entire specimen is inked black and sectioning demonstrates a gray firm cut surface measuring 2.5 x 2 x 1.0 cm. Representative sections are

[page 2 of 2]
submitted to [REDACTED]. An additional section is submitted in cytogenetics media for study. The remaining lesional tissue is submitted entirely in A1-A3; A4, representative adjacent soft tissue.

(Dictated by: [REDACTED]) ([REDACTED])

MICROSCOPIC DESCRIPTION: Histologic examination performed.

Any tests performed using Analytic Specific Reagents (ASR) were developed and validated by [REDACTED]. The U.S. Food and Drug Administration has not approved these tests but has determined that such clearance or approval is not necessary. These tests should be regarded as a clinical assay for standard medical care.

The [REDACTED] was present during the formal review and interpretation of all slides and ancillary studies, (if performed), with the [REDACTED]. Specimens with only gross examination were reviewed and interpreted by the [REDACTED].

[REDACTED]

Dual/Synchronous Primary	Noted	

Source: NCI Genomic Data Commons file 9637f15d-009e-423d-8a19-29a83a32303f (TCGA-3R-A8YX.D4FCD1DB-99F2-424F-95CC-F242F3B1B5DB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).